Somatic mutation profile of tumor specimen C3N-00721-01 (aliquot CPT0204010006) from CPTAC case C3N-00721, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G3.
Specimen C3N-00721-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb3effad-b24b-4a45-b39b-96ab38a1737e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00721-71 (Blood Derived Normal), aliquot CPT0204210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/989449a9-ba7e-4103-9497-d48e8a6a9b4c

The open-access MAF lists 96 somatic variants for this specimen: 73 protein-altering or splice-affecting, 17 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 17, Frame Shift Del 8, Nonsense Mutation 4, Intron 4, Splice Site 3, 5'UTR 2, In Frame Del 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM3 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV58643397; called by muse, mutect2, varscan2
- ADAMTS6 | c.630G>A p.S210= | Splice Region (SNP) | VAF 7/109 reads (6%) | catalogued as rs1335518133, COSV66859520; called by muse, mutect2
- ATP9A | c.982T>C p.W328R | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs757123826; called by muse, mutect2, varscan2
- BCL7C | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1200306786; called by muse, mutect2
- COL4A1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 78/457 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.08); catalogued as COSV64630622; called by muse, mutect2, varscan2
- DMD | c.10948C>A p.Q3650K | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as COSV100627203, COSV58902821; called by muse, mutect2, varscan2
- GIT1 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.608); catalogued as rs149623045; called by muse, mutect2, varscan2
- MUC17 | c.2294G>A p.S765N | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs71557226, COSV60281858; called by muse, mutect2, varscan2
- MYO15A | c.10136C>T p.S3379L | Missense Mutation (SNP) | VAF 70/431 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as rs546575046; called by muse, mutect2, varscan2
- NFE2L3 | c.1063A>G p.T355A | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs777143712; called by muse, mutect2, varscan2
- OR51F1 | c.688del p.I230Lfs*36 | Frame Shift Del (DEL) | VAF 29/191 reads (15%) | catalogued as COSV58580279; called by mutect2, pindel, varscan2
- RIMBP2 | c.2749G>C p.D917H | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756185566; called by muse, mutect2, varscan2
- SLC10A2 | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs750569881; called by muse, mutect2, varscan2
- ST3GAL1 | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 55/274 reads (20%) | PolyPhen benign (0); catalogued as rs376880755; called by muse, mutect2, varscan2
- SVEP1 | c.5839G>A p.A1947T | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.666); catalogued as rs1208235524, COSV52842227; called by muse, mutect2, varscan2
- TENM2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 379/824 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as rs752353786, COSV72852991; called by muse, mutect2, varscan2
- VHL | c.439del p.I147Ffs*12 | Frame Shift Del (DEL) | VAF 65/350 reads (19%) | catalogued as CM106926, COSV56543105, COSV56564700, COSV99846812; called by mutect2, pindel, varscan2
- ABCC3 | c.3337G>A p.V1113M | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); called by muse, mutect2
- ACACA | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 84/422 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.69); called by mutect2, varscan2
- ACAD10 | c.2936A>T p.H979L | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2
- ANKFN1 | c.3170A>C p.D1057A (on ENST00000653862; = p.D910A on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/327 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- BEST4 | c.468C>G p.H156Q | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BRD7 | c.428T>A p.L143Q | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTBD8 | c.3302C>G p.S1101C (on ENST00000636805 / NM_001376131.1; = p.S588C on NM_015237.4) | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- C2orf74 | c.196A>T p.K66* | Nonsense Mutation (SNP) | VAF 41/398 reads (10%) | called by muse, mutect2, varscan2
- CFAP20 | c.150A>C p.E50D | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLCA4 | c.525C>A p.Y175* | Nonsense Mutation (SNP) | VAF 26/194 reads (13%) | called by muse, mutect2, varscan2
- CLEC16A | c.1817_1834del p.X606_splice | Splice Site (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel, varscan2
- COL3A1 | c.2570A>C p.Q857P | Missense Mutation (SNP) | VAF 54/460 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL4A2 | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL5A1 | c.4532C>T p.S1511F | Missense Mutation (SNP) | VAF 71/423 reads (17%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- DBN1 | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 69/687 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DIS3 | c.2005C>A p.L669I | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUOX1 | c.1094A>G p.N365S | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- EDIL3 | c.110G>C p.C37S | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPHB3 | c.2732+1del | Frame Shift Del (DEL) | VAF 34/125 reads (27%) | called by mutect2, pindel, varscan2
- ETF1 | c.28A>T p.R10W | Missense Mutation (SNP) | VAF 31/468 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- FSIP2 | c.7200A>C p.L2400F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2
- HMSD | c.226T>G p.F76V | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HPS4 | c.1627C>G p.L543V | Missense Mutation (SNP) | VAF 63/313 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HTT | c.6010C>G p.L2004V | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- INF2 | c.329A>C p.N110T | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ITSN2 | c.4090-1G>T p.X1364_splice | Splice Site (SNP) | VAF 49/147 reads (33%) | called by muse, mutect2, varscan2
- JMJD6 | c.942-4_962del p.X314_splice | Splice Site (DEL) | VAF 26/138 reads (19%) | called by mutect2, pindel
- KCNC1 | c.971T>G p.L324R | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL12 | c.921G>C p.Q307H | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- MARCHF7 | c.694_695del p.E232Ifs*16 | Frame Shift Del (DEL) | VAF 51/184 reads (28%) | called by mutect2, pindel, varscan2
- MEP1A | c.1701_1703del p.W567_S568delinsC | In Frame Del (DEL) | VAF 20/191 reads (10%) | called by mutect2, pindel
- MRPL54 | c.314del p.K105Rfs*28 | Frame Shift Del (DEL) | VAF 35/337 reads (10%) | called by mutect2, pindel, varscan2
- MYO15A | c.10135T>C p.S3379P | Missense Mutation (SNP) | VAF 72/437 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- MYO6 | c.2273T>A p.F758Y | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NRDE2 | c.676A>T p.K226* | Nonsense Mutation (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2, varscan2
- PELI3 | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- PLCD3 | c.219G>C p.K73N | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PRKCB | c.17C>A p.A6E | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by muse, mutect2
- RIBC2 | c.809C>G p.P270R | Missense Mutation (SNP) | VAF 97/584 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- RPRD2 | c.1370G>C p.S457T | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RYR2 | c.400T>A p.S134T | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SACS | c.12134del p.L4045* | Frame Shift Del (DEL) | VAF 23/151 reads (15%) | called by mutect2, pindel, varscan2
- SHMT2 | c.220_223delinsC p.I74_A75delinsP | In Frame Del (DEL) | VAF 31/162 reads (19%) | called by pindel, varscan2*
- SIPA1L3 | c.2457G>C p.R819S | Missense Mutation (SNP) | VAF 112/356 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SLCO1C1 | c.1904C>A p.S635* | Nonsense Mutation (SNP) | VAF 21/254 reads (8%) | called by muse, mutect2
- SRSF2 | c.513dup p.K172Qfs*43 | Frame Shift Ins (INS) | VAF 35/202 reads (17%) | called by mutect2, pindel, varscan2
- STAG2 | c.2742G>C p.Q914H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.033); called by muse, varscan2
- STARD3 | c.914A>T p.E305V | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- STING1 | c.508del p.L170* | Frame Shift Del (DEL) | VAF 24/138 reads (17%) | called by mutect2, pindel, varscan2
- SVEP1 | c.5840C>T p.A1947V | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- TECR | c.146C>G p.S49C | Missense Mutation (SNP) | VAF 97/308 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- UGGT2 | c.3866del p.Y1289Lfs*3 | Frame Shift Del (DEL) | VAF 31/235 reads (13%) | called by mutect2, pindel, varscan2
- UTRN | c.5779A>T p.I1927F | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- WDR87 | c.6225A>T p.K2075N | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- ZNF837 | c.251C>A p.T84N | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2
- ZNF837 | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOBEC3A | c.105C>T p.Y35= | Silent (SNP) | VAF 22/169 reads (13%) | catalogued as rs757927103; called by muse, mutect2, varscan2
- COL11A2 | c.426C>T p.L142= | Silent (SNP) | VAF 153/819 reads (19%) | called by muse, mutect2, varscan2
- DLG5 | c.147A>T p.G49= | Silent (SNP) | VAF 151/532 reads (28%) | called by muse, mutect2, varscan2
- FASTKD5 | c.81T>C p.S27= | Silent (SNP) | VAF 41/304 reads (13%) | called by muse, mutect2, varscan2
- FEM1B | c.1470G>C p.L490= | Silent (SNP) | VAF 38/194 reads (20%) | called by muse, mutect2, varscan2
- GADL1 | c.258G>A p.L86= | Silent (SNP) | VAF 26/167 reads (16%) | catalogued as COSV56986801; called by muse, mutect2, varscan2
- IQGAP3 | c.411G>A p.R137= | Silent (SNP) | VAF 105/339 reads (31%) | catalogued as rs142267353; called by muse, mutect2, varscan2
- MUC16 | c.28741C>T p.L9581= | Silent (SNP) | VAF 29/166 reads (17%) | catalogued as COSV67453307; called by muse, mutect2, varscan2
- NOTCH1 | c.5787G>A p.E1929= | Silent (SNP) | VAF 101/659 reads (15%) | catalogued as COSV99489269; called by muse, mutect2, varscan2
- OR4N2 | c.789G>A p.R263= | Silent (SNP) | VAF 80/488 reads (16%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.483C>A p.G161= | Silent (SNP) | VAF 30/406 reads (7%) | called by muse, mutect2
- PCDHGB3 | c.1458T>A p.L486= | Silent (SNP) | VAF 325/777 reads (42%) | called by muse, mutect2, varscan2
- PLK3 | c.207C>T p.G69= | Silent (SNP) | VAF 58/294 reads (20%) | called by muse, mutect2, varscan2
- RGR | c.117C>T p.F39= | Silent (SNP) | VAF 217/767 reads (28%) | catalogued as COSV100812971; called by muse, mutect2, varscan2
- TBR1 | c.1984C>A p.R662= | Silent (SNP) | VAF 99/317 reads (31%) | called by muse, mutect2, varscan2
- TMEM63C | c.1227C>A p.R409= | Silent (SNP) | VAF 49/250 reads (20%) | catalogued as COSV53602615; called by muse, mutect2, varscan2
- ZNF292 | c.7459T>C p.L2487= | Silent (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- AC011773.3 | n.668-3739T>C | Intron (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- DHODH | c.435-29T>A | Intron (SNP) | VAF 88/686 reads (13%) | called by muse, mutect2
- KIRREL3 | c.1696+34G>A | Intron (SNP) | VAF 41/263 reads (16%) | catalogued as COSV101375237; called by muse, mutect2, varscan2
- R3HDM1 | c.-29C>A | 5'UTR (SNP) | VAF 11/50 reads (22%) | catalogued as rs373495593, COSV51526058; called by muse, mutect2, varscan2
- RUNX1 | c.-32T>G | 5'UTR (SNP) | VAF 115/363 reads (32%) | called by muse, mutect2, varscan2
- SDR39U1 | c.206+85T>C | Intron (SNP) | VAF 88/539 reads (16%) | catalogued as rs185932310; called by muse, mutect2, varscan2
